Somatic mutation profile of tumor specimen MP2PRT-PAUYUG-TMP1-A (aliquot MP2PRT-PAUYUG-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUYUG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,010 days).
Specimen MP2PRT-PAUYUG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5916daa4-2155-4048-b568-f81354b79314.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYUG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYUG-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc21f6a1-4efc-463f-9e04-1e14bc5d70ee

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF26 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62844654; called by muse, mutect2
- FGD1 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 199/301 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as rs1401996796; called by muse, mutect2, varscan2
- MYBPC2 | c.1706C>T p.T569I | Missense Mutation (SNP) | VAF 145/347 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV63096442; called by muse, mutect2, varscan2
- MYOF | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 26/393 reads (7%) | catalogued as rs370504948, COSV63702542; called by muse, mutect2
- PDZRN3 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 14/498 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV55207359; called by muse, mutect2
- PIK3R2 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.955); catalogued as rs550250836, COSV55849291, COSV99717158; called by muse, mutect2, varscan2
- RXFP3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 88/608 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs754698803, COSV57504049; called by muse, varscan2
- SETX | c.4036C>T p.Q1346* | Nonsense Mutation (SNP) | VAF 93/287 reads (32%) | catalogued as rs1564539757, CM096477; called by muse, mutect2, varscan2
- BECN2 | c.1244T>A p.L415H | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FNDC1 | c.3038C>T p.S1013F | Missense Mutation (SNP) | VAF 64/657 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- GLI4 | c.1088G>A p.S363N | Missense Mutation (SNP) | VAF 51/425 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PDZD8 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 127/398 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRPF8 | c.5076G>A p.M1692I | Missense Mutation (SNP) | VAF 70/675 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- TRIM11 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2
- TRIR | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 32/541 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- ZBTB33 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- DAXX | c.726G>A p.L242= | Silent (SNP) | VAF 64/730 reads (9%) | called by muse, mutect2
- OR14I1 | c.660C>T p.F220= | Silent (SNP) | VAF 15/269 reads (6%) | called by muse, mutect2
- RASGRF2 | c.1644G>T p.G548= | Silent (SNP) | VAF 30/219 reads (14%) | called by muse, mutect2, varscan2
- TIMM44 | c.810C>T p.N270= | Silent (SNP) | VAF 126/351 reads (36%) | catalogued as rs139986376; called by muse, mutect2, varscan2
- NRG1 | c.502+31108C>T | Intron (SNP) | VAF 20/500 reads (4%) | catalogued as COSV99827457; called by muse, mutect2
